Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A3KD, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A3KD-01A (Primary Tumor).

[page 1 of 3]
FOR OFFICIAL USE ONLY - PERSONAL DATA - PRIVACY

SURGICAL PATHOLOGY REPORT

Patient:		Specimen #:
FMP/SSN:		
DOB/Age/Sex:	(Age:) F Race:	Taken:
Location:		Received:
Physician(s):		Reported:

SPECIMEN:

A: RIGHT SENTINEL NODE #1 B: RIGHT BREAST SENTINEL NODE #2
C: RIGHT BREAST LUMPECTOMY

FINAL DIAGNOSIS:

ICD-O-3 carcinoma, infiltrating mucinous 8480/3
site: breast, NOS C50.9 12/13/11

- A. LYMPH NODE, RIGHT AXILLA SENTINEL #1, BIOPSY:
- ONE LYMPH NODE POSITIVE FOR MICROMETASTASIS (A1, LARGEST FOCUS, 0.27 MM - measured microscopically); ISOLATED TUMOR CELLS ALSO PRESENT IN EXTRACAPSULAR LYMPHATIC SPACES.
- ONE LYMPH NODE POSITIVE FOR ISOLATED TUMOR CELLS (A2).
- ONE LYMPH NODE NEGATIVE FOR TUMOR BY H&E LIGHT MICROSCOPY AND CYTOKERATIN IMMUNOHISTOCHEMISTRY (A3).
- B. LYMPH NODE, RIGHT AXILLA SENTINEL #2, BIOPSY:
- ONE LYMPH NODE NEGATIVE FOR TUMOR BY H&E LIGHT MICROSCOPY AND CYTOKERATIN IMMUNOHISTOCHEMISTRY; HOWEVER, ISOLATED TUMOR CELLS ARE PRESENT IN EXTRACAPSULAR LYMPHATIC SPACES.
- C. BREAST, RIGHT, LUMPECTOMY:
- WELL-DIFFERENTIATED (GRADE I/III) INFILTRATING MUCINOUS (COLLOID) CARCINOMA.
- * NOTTINGHAM HISTOLOGIC SCORE: 4 OUT OF 9 (Tubule formation = 2; Nuclear pleomorphism = 1; Mitotic activity = 1).
- * TUMOR SIZE: 4.0 CM (measured grossly).
- * TUMOR NECROSIS OR CALCIFICATIONS: ABSENT.
- * VENOUS/LYMPHATIC INVASION: FOCI HIGHLY SUSPICIOUS FOR LYMPHATIC INVASION.
- * MARGINS: POSITIVE. INFILTRATING CARCINOMA IS PRESENT AT THE INKED BLUE (SUPERIOR, E.G., SLIDE C2), ORANGE (ANTERIOR, E.G., SLIDE C3), RED (MEDIAL, E.G., SLIDE C8), AND BLACK (DEEP, E.G., SLIDE C11) TISSUE EDGES.
- * IN SITU COMPONENT: FOCAL DUCTAL CARCINOMA IN SITU, LOW NUCLEAR GRADE (DCIS, GRADE 1); SOLID AND FOCAL CRIBRIFORM TYPES.
- * LYMPH NODES: ONE OUT OF FOUR SENTINEL LYMPH NODES POSITIVE FOR MICROMETASTASIS (please see part "A" and "B").
- * ESTROGEN RECEPTORS: POSITIVE (>95%, please see report
- * PROGESTERONE RECEPTORS: POSITIVE (90%, please see report
- * HER2NEU by IHC: NEGATIVE (Score 1+, please see report

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

FINAL DIAGNOSIS (continued):

- * PATHOLOGIC STAGE: pT2N1mi(.
- ADDITIONAL PATHOLOGIC FINDINGS:
- * STROMAL SCLEROSIS AND FOCAL MICROCYST FORMATION.
- * FOCAL PRIOR BIOPSY SITE CHANGES.

** Report Electronically Signed Out **

=====

CLINICAL DIAGNOSIS AND HISTORY:

Right breast cancer -year-old female.

PRE-OPERATIVE DIAGNOSIS:

None provided.

POST-OPERATIVE DIAGNOSIS:

None provided.

GROSS DESCRIPTION:

A: Received fresh, labeled with the patient's name and designated, "Right Breast Sentinel Node #1" consists of three pink-tan lymph nodes measuring 0.3 cm, 0.8 x 0.5 x 0.4 cm, and 1.5 x 1.2 x 0.5 cm in greatest dimension. Sectioning the larger lymph node reveals pink-red otherwise unremarkable parenchyma. The specimen is entirely submitted as follows: A1- one lymph node, bisected; A2- one lymph node; A3- one lymph node. A matched section of A2 is submitted in OCT for protocol. Time in formalin:

B: Received in formalin, labeled with the patient's name and designated, "Right Breast Sentinel Node #2" consists of a 0.4 x 0.3 x 0.3 cm tan lymph node. The lymph node is bisected and submitted in its entirety. Time in formalin:

C: Received fresh, labelled with the patient's name and designated, "Right Breast Lumpectomy" consists of an ovoid portion of firm, yellow-tan breast tissue oriented with a short stitch-superior; and long stitch-lateral. The specimen measures 6.5 cm from superior to inferior; 5.5 cm from medial to lateral and 2.0 cm from anterior to deep. The specimen is inked as follows: superior-blue; inferior-green; medial-red; lateral-yellow; anterior-orange; and deep-black. Serial sections reveal a firm, gritty, pink-tan mass measuring 4.0 x 3.5 x 1.5

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

cm. The mass show well defined borders along the superior portion of the specimen with patchy, ill defined distribution throughout the remainder of the specimen, involving approximately 75% of the cut surface. The mass abuts the superior, anterior, deep, and medial margins. The surrounding breast tissue is dense, pink and white fibrous tissue. No other mass lesions are identified. Representative sections are sequentially submitted from superior to inferior as follows: C1-C2- mass with superior margin; C3-C5- mass with additional margins; C6- adjacent normal; C7- mass with additional margins; C8- mass with additional margins; C9- mass with lateral margin; C10- mass with additional margins; C11- mass with additional margins; C12- inferior margin. Matched sections of C3, C5, C7, and C9-C11 are submitted in OCT and paraffin for protocol.

Time in formalin:

Source: NCI Genomic Data Commons file 6b6dddc0-3158-4d4a-ad8e-4a562ed0b5bd (TCGA-A2-A3KD.3E4717BA-E9AE-45F9-9696-F8928D9FCECC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).